Somatic mutation profile of tumor specimen 0DDEQF from CCDI case PBBNPB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Lymph nodes of inguinal region or leg; Age at diagnosis: 14.9 years (5,438 days).
Specimen 0DDEQF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96f3c034-e71a-42e3-af9b-ee4f184db062.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDEQB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/75e8a243-8c3b-4283-baf9-e03a313648d6

The open-access MAF lists 26 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Intron 4, Silent 4, Nonsense Mutation 2, RNA 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BLVRB | c.621G>T p.*207Yext*? | Nonstop Mutation (SNP) | VAF 22/608 reads (4%) | catalogued as COSV99648023; called by muse, mutect2
- CCDC141 | c.2569C>T p.R857W | Missense Mutation (SNP) | VAF 165/888 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs753311518, COSV55379422; called by muse, mutect2, varscan2
- CSMD3 | c.1561G>A p.A521T (on ENST00000297405 / NM_001363185.1; = p.A417T on NM_052900.3) | Missense Mutation (SNP) | VAF 183/1778 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as rs140758499; called by muse, mutect2, varscan2
- MAGEC1 | c.3371C>T p.S1124L | Missense Mutation (SNP) | VAF 167/348 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.177); catalogued as rs747835069, COSV53576803, COSV53580170; called by muse, mutect2, varscan2
- RSPO2 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 133/1365 reads (10%) | SIFT tolerated (1); PolyPhen probably damaging (0.993); catalogued as COSV52647157; called by muse, mutect2, varscan2
- WDR81 | c.2366C>T p.T789M | Missense Mutation (SNP) | VAF 24/382 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs748844854; called by muse, mutect2
- DCDC1 | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 34/979 reads (3%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); called by muse, mutect2
- EYS | c.2244C>A p.C748* | Nonsense Mutation (SNP) | VAF 264/958 reads (28%) | called by mutect2, varscan2
- GABRA1 | c.678C>G p.D226E | Missense Mutation (SNP) | VAF 47/1400 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.245); called by muse, mutect2
- LHFPL1 | c.549C>A p.C183* | Nonsense Mutation (SNP) | VAF 30/404 reads (7%) | called by muse, mutect2
- LRRC8B | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 203/811 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- PLXNB3 | c.5587C>A p.Q1863K | Missense Mutation (SNP) | VAF 179/560 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- PSPH | c.346G>T p.V116L | Missense Mutation (SNP) | VAF 116/711 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.041); called by mutect2, varscan2
- SERPING1 | c.1360G>A p.V454M | Missense Mutation (SNP) | VAF 50/329 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SPEG | c.1256C>T p.S419L | Missense Mutation (SNP) | VAF 70/568 reads (12%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TMC5 | c.2168A>C p.E723A (on ENST00000396229 / NM_001105248.1; = p.E477A on NM_024780.5) | Missense Mutation (SNP) | VAF 36/924 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); called by muse, mutect2
- DACH2 | c.1527T>A p.L509= | Silent (SNP) | VAF 170/620 reads (27%) | called by muse, mutect2, varscan2
- SERPINB7 | c.138T>G p.A46= | Silent (SNP) | VAF 40/1332 reads (3%) | catalogued as COSV60536212; called by muse, mutect2
- SLC38A2 | c.177G>A p.K59= | Silent (SNP) | VAF 86/1780 reads (5%) | called by muse, mutect2
- SMC4 | c.186G>A p.L62= | Silent (SNP) | VAF 104/807 reads (13%) | catalogued as rs1451645255; called by muse, mutect2, varscan2
- BTN2A1 | c.983-181A>C | Intron (SNP) | VAF 40/950 reads (4%) | catalogued as rs918554327; called by muse, mutect2
- CR1 | c.487+12042G>T | Intron (SNP) | VAF 219/1235 reads (18%) | called by muse, mutect2, varscan2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 12/284 reads (4%) | called by muse, mutect2
- MUC19 | n.11359G>A | RNA (SNP) | VAF 10/38 reads (26%) | catalogued as rs1358019138; called by muse, varscan2
- PRB3 | c.605-28A>C | Intron (SNP) | VAF 10/85 reads (12%) | catalogued as rs770486309, COSV54388034; called by muse, varscan2
- ZNF274 | c.852+49C>G | Intron (SNP) | VAF 19/76 reads (25%) | called by muse, mutect2, varscan2
